Gene-level copy-number profile of tumor specimen REBC-ADJX-TTP1-A from REBC case REBC-ADJX, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADJX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fb60b8cf-22d3-4c7e-95c7-b0a20a82dfe6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADJX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/dd93dcd5-dde3-429b-a1f2-23be75e97130

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 58,340; copy number 3: 44; copy number 4: 6; copy number 5: 6; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,391,707, 5 genes, copy number 5: AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2.
- chr2:197,569–266,398, 2 genes, copy number 6 (within-gene range 2–6): AC079779.1, SH3YL1.
- chr3:196,739,857–196,832,647, 1 gene, copy number 6 (within-gene range 2–6): PAK2.
- chr3:196,784,980–196,785,086, 1 gene, copy number 6: RNU6-42P.
- chr15:76,993,359–77,037,475, 1 gene, copy number 5: PSTPIP1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
